Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6682, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6682-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
Rectosigmoid adenocarcinoma.

Specimens Submitted:
1: Colon, sigmoid and upper rectum; resection
2: Hernia contents
3: Portion of omentum
4: Base of IMA lymph node
5: Proximal margin
6: Distal margin

DIAGNOSIS:

1. Colon, sigmoid and upper rectum; resection:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Rectosigmoid
Tumor Size:
Length is 6.8 cm
Width is 8.5 cm
Maximal thickness is 0.4 cm
Tumor Budding:
Absent
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Tubular adenoma
Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Not identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Not identified
Surgical Margins:

** Continued on next page **

[page 2 of 5]
Free of tumor
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:
Unremarkable
Lymph Nodes:
Number with metastasis: 0
Total number examined: 24
Tumor deposits in pericorectal soft tissue:
Not Identified
Tumor Staging (AJCC 7th Edition):
pT3 (Tumor invades through the muscularis propria into
pericorectal tissues)
Lymph Node Stage (AJCC 7th Edition):
N0 (No regional lymph node metastasis)

2. Hernia contents; excision:
-Benign skin and fibroadipose tissue.
3. Omentum, "portion of"; omentectomy:
-Benign mature adipose tissue.
4. Lymph node, "base of IMA;" excision:
-Two benign lymph nodes (0/2).
5. Colon, proximal margin; excision:
-Benign segment of colon.
6. Colon, distal margin; excision:
-Benign segment of colon.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Gross Description:

1). The specimen is received fresh and is labeled "Sigmoid and upper rectum
stitch marks proximal." It consists of a rectosigmoid colon that measures
19.0 x 7.5 cm. The serosal surface is smooth. The radial resection margin is
inked black, and the specimen is opened to reveal a tumor that is located
12.5 cm from the proximal margin and 5.5 cm from the distal margin. The
tumor measures 6.8 cm in length and 8.5 cm in width. Serial sectioning
reveals tumor invasion to a depth of 0.9 cm, extending through the
muscularis grossly approaching into the underlying pericolic fat, which is
4.5 cm from the closest radial margin. The remaining mucosa shows grossly
unremarkable mucosal folds. Pericolic and peri-rectal adipose tissue is

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
thoroughly examined for lymph nodes, and all possible nodes are submitted.
Representative sections are submitted. TPS is submitted.

Summary of sections:
PM - proximal margin
DM - distal margin
RM - radial margin
T - tumor
RS - uninvolved mucosa
LN - lymph nodes
BLN - bisected lymph node

2). The specimen is received fresh, labeled "Hernia contents." It consists of multiple lobulated fibrofatty soft tissue fragments measuring 17.0 x 4.5 x 5.0 cm in aggregate with multiple fragments of irregular skin measuring 9.5 x 4.5 cm in aggregate. The specimen is sectioned to reveal grossly unremarkable lobulated adipose tissue, no discrete lesions or gross abnormalities are identified. Representative sections are submitted.

Summary of sections:
U - undesignated

3). The specimen is received fresh, labeled "Omentum." It consists of a 18 x 15 x 5.5 cm portion of lobulated adipose tissue consistent with omentum. Serial sectioning reveals yellow-tan fatty lobulated appearance with focal areas of hemorrhage. Representative sections are submitted.

Summary of sections:
O - omentum

4). The specimen is received in formalin labeled "Base of IMA lymph nodes." It consists of two lymph nodes measuring 0.3 x 0.3 cm and 1.5 x 1.4 cm in greatest dimensions. Lymph nodes are entirely submitted.

Summary of sections:
LN - lymph nodes
TLN - trisected lymph node

5). The specimen is received in formalin wrapped around an anastomotic pin, labeled "Proximal margin" and consists of a ring of pink tan soft tissue measuring 3.0 x 1.8 x 1.0 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

** Continued on next page **

[page 4 of 5]
6). The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 2.0 x 1.7 x 0.8 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Colon, sigmoid and upper rectum; resection

Block	Sect.	Site	PCs
5		BLN	10
2		DM	2
10		LN	20
2		PM	2
1		RM	1
1		RS	1
4		T	4

Part 2: Hernia contents

Block	Sect.	Site	PCs
2		U	2

Part 3: Portion of omentum

Block	Sect.	Site	PCs
3		o	3

Part 4: Base of IMA lymph node

Block	Sect.	Site	PCs
1		ln	1
1		tlm	1

Part 5: Proximal margin

Block	Sect.	Site	PCs
1		u	1

Part 6: Distal margin

Block	Sect.	Site	PCs
1		u	1

** Continued on next page **

[page 5 of 5]
[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file d77fb8ab-1d62-4e94-b62c-02295193d3d1 (TCGA-DC-6682.0D4BF2AD-1FD0-4F44-9919-7D93320F8135.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).